Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A24W, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A24W-01A (Primary Tumor).

Final Diagnosis

Breast, right, total mastectomy: Infiltrating ductal carcinoma, Nottingham grade II (of III), [tubules 3/3, nuclei 2/3, mitoses 1/3; Nottingham score 6/9], forming a 2.1 x 1.4 x 1.1 cm mass located in the central breast (AJCC pT2). Ductal carcinoma in situ, intermediate nuclear grade, comprising approximately 5-25% of tumor volume. Angiolymphatic invasion is present. The non-neoplastic breast parenchyma shows proliferative fibrocystic changes. Calcifications present in malignant ducts. Biopsy site changes present. The tumor does not involve the nipple, overlying skin, or underlying chest wall. All surgical resection margins, including deep margin, are negative for tumor (minimum tumor free margin, 2.1 cm, deep margin).

Lymph nodes, right axillary sentinel Nos. 1A, 1B, 1C and 2, sentinel biopsy: Three (of 4) right axillary sentinel lymph nodes are positive for metastatic carcinoma (>2.0 mm) [AJCC pN1(sn)]. Extranodal extension is not present. Blue dye is identified in lymph nodes Nos. 1A and 1B. Lymph node No. 1C does not contain blue dye.

Lymph nodes, right axillary, dissection: Multiple (18) right axillary lymph nodes are negative for tumor.

Breast, left, total mastectomy: Ductal carcinoma in situ, micropapillary and cribriform types, low nuclear grade without intraluminal necrosis, involving an area over 5.7 x 2.3 x 1.4 cm [AJCC pTis]. The non-neoplastic breast parenchyma shows nonproliferative fibrocystic changes. Calcifications are present in malignant ducts. Biopsy site changes are present. Nipple and skin are without diagnostic abnormality. All surgical resection margins are negative for tumor (minimum tumor free margin, 1.5 cm, deep margin). ↓

bilateral breast SA

1 CD-0-3
carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9
hr
4/25/11

Source: NCI Genomic Data Commons file 7a8149b2-84af-4fc1-9d50-94c6f6805a63 (TCGA-AR-A24W.0F2464F7-4108-4700-B2EC-17BC6C432D42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).